Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6679, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6679-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
Sigmoid cancer __ 25cm anterior resection.

Specimens Submitted:
1: Sigmoid colon
2: Proximal ring
3: Distal ring

DIAGNOSIS:
1. Sigmoid colon:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Sigmoid colon
Tumor Size:
Length is 2.8 cm
Width is 6.5 cm
Maximal thickness is 0.7 cm
Tumor Budding:
Focal
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Not identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Not identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified

** Continued on next page **

[page 2 of 4]
Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 21

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

2. Colon, proximal ring excision:

- Colonic mucosa with hyperplastic features.
- No tumor seen.

3. Colon, distal ring. excision:

- Colonic mucosa with hyperplastic features.
- No tumor seen.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh and is labeled "Sigmoid colon". It consists of a portion of sigmoid colon that measures 18.5cm in length x 10.0 cm in open circumference at the distal margin. The serosal surface is pink tan and unremarkable. The radial resection margin is inked black and the specimen is opened to reveal a tumor that is located 9.0 cm from the proximal margin and 6.0 cm from the distal margin. The tumor measures 2.8 cm in length and 6.5 cm in width. Serial sectioning reveals tumor extending to a depth of 0.7 cm, through the muscularis and grossly approaching into the underlying pericolic fat. The tumor is 4.0 cm from the closest radial margin. The remaining mucosa shows tan-yellow grossly unremarkable mucosal folds. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

** Continued on next page **

[page 3 of 4]
T - tumor
RS - uninvolved mucosa
LN - lymph nodes
BLN - bisected lymph node

2). The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a green plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2.5 x 1.6 x 1.0 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

3). The specimen is received in formalin, labeled "Distal ring" and consists of a ring of pink tan soft tissue measuring 2.8 x 1.6 x 1.1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:
Part 1: Sigmoid colon

Block	Sect.	Site	PCs
6		BLN	11
3		DM	3
4		LN	15
2		PM	2
1		RM	1
2		RS	2
3		T	3

Part 2: Proximal ring

Block	Sect.	Site	PCs
3		U	5

Part 3: Distal ring

Block	Sect.	Site	PCs
3		U	6

** Continued on next page **

[page 4 of 4]
[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file f32e4e6e-5db6-48a8-a180-29379e4ec739 (TCGA-CM-6679.59284F77-B8BD-4E43-A940-70C2A80442F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).